Somatic mutation profile of tumor specimen TCGA-EJ-A65E-01A (aliquot TCGA-EJ-A65E-01A-11D-A29Q-08) from TCGA case TCGA-EJ-A65E, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma with mixed subtypes; Tissue or organ of origin: Prostate gland; Age at diagnosis: 67.2 years (24,558 days).
Specimen TCGA-EJ-A65E-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 75d295be-f154-4413-aca1-3d71b26c8e49.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EJ-A65E-10A (Blood Derived Normal), aliquot TCGA-EJ-A65E-10A-01D-A29Q-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/88f71db7-19aa-4a7e-9f35-031ba08f64ad

The open-access MAF lists 38 somatic variants for this specimen: 29 protein-altering or splice-affecting, 9 silent.
By variant classification: Missense Mutation 25, Silent 9, Splice Region 1, Splice Site 1, Frame Shift Del 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1526G>C p.G509A (on ENST00000288602 / NM_001374244.1; = p.G469A on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 25/119 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.933); catalogued as rs121913355, CM060876, COSV56061424, COSV56062352, COSV56065622; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- SPOP | c.304T>G p.F102V | Missense Mutation (SNP) | VAF 24/71 reads (34%) | hotspot (GDC flag); SIFT tolerated (0.11); PolyPhen probably damaging (0.988); catalogued as rs1057519964, COSV61653339, COSV61655858; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ADORA3 | c.895G>T p.A299S | Missense Mutation (SNP) | VAF 22/56 reads (39%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as COSV53985121, COSV53986103; called by muse, mutect2, varscan2
- C2CD2L | c.1948C>T p.R650C | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs761910846, COSV60883679, COSV60884184; called by muse, mutect2, varscan2
- CYBB | c.862T>A p.F288I | Missense Mutation (SNP) | VAF 66/111 reads (59%) | SIFT tolerated (0.09); PolyPhen benign (0.139); catalogued as COSV66085572; called by muse, mutect2, varscan2
- DSCAM | c.2797C>T p.Q933* | Nonsense Mutation (SNP) | VAF 14/53 reads (26%) | catalogued as COSV68028612; called by muse, mutect2, varscan2
- DSG1 | c.2794G>A p.G932S | Missense Mutation (SNP) | VAF 68/244 reads (28%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.853); catalogued as rs370600690; called by muse, mutect2, varscan2
- FBN1 | c.3674C>T p.P1225L | Missense Mutation (SNP) | VAF 16/75 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.054); catalogued as rs775532488, CM148676, COSV57319531; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GPA33 | c.755T>C p.I252T | Missense Mutation (SNP) | VAF 34/112 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.02); catalogued as rs1340557264, COSV63301309; called by muse, mutect2, varscan2
- HEATR3 | c.1780G>T p.D594Y | Missense Mutation (SNP) | VAF 33/116 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV53529737; called by muse, mutect2, varscan2
- HIC2 | c.449G>A p.R150K | Missense Mutation (SNP) | VAF 3/37 reads (8%) | SIFT tolerated (0.86); PolyPhen benign (0.007); catalogued as rs1294176082; called by muse, mutect2
- NUFIP2 | c.438A>T p.K146N | Missense Mutation (SNP) | VAF 15/99 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.103); catalogued as COSV56603692; called by muse, mutect2, varscan2
- OR10J3 | c.638G>C p.G213A | Missense Mutation (SNP) | VAF 44/130 reads (34%) | SIFT tolerated (0.51); PolyPhen benign (0.034); catalogued as COSV59954725; called by muse, mutect2, varscan2
- OTOF | c.784G>A p.E262K | Missense Mutation (SNP) | VAF 11/61 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1024084525, COSV55505817; called by muse, mutect2, varscan2
- P4HA1 | c.548C>G p.T183R | Missense Mutation (SNP) | VAF 11/107 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.872); catalogued as COSV54962309; called by muse, mutect2, varscan2
- PPP1CA | c.440A>T p.K147I | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.58); catalogued as COSV100335049, COSV56703255; called by muse, mutect2, varscan2
- PPP1R42 | c.596T>C p.I199T | Missense Mutation (SNP) | VAF 6/15 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.039); catalogued as rs781592860, COSV61207885; called by muse, mutect2, varscan2
- PPP2R1B | c.1025T>G p.I342R | Missense Mutation (SNP) | VAF 13/32 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.369); catalogued as COSV59535902; called by muse, mutect2
- RBM25 | c.2428G>A p.D810N | Missense Mutation (SNP) | VAF 21/74 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56200420; called by muse, varscan2
- SGSM3 | c.2212G>C p.V738L | Missense Mutation (SNP) | VAF 38/141 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.049); catalogued as COSV50652733; called by muse, mutect2, varscan2
- SLC26A9 | c.951C>T p.R317= | Splice Region (SNP) | VAF 16/60 reads (27%) | catalogued as rs760498151, COSV61602677; called by muse, mutect2, varscan2
- SLC49A4 | c.825A>C p.R275S | Missense Mutation (SNP) | VAF 33/92 reads (36%) | SIFT tolerated (0.18); PolyPhen benign (0.013); catalogued as COSV53747451; called by muse, mutect2, varscan2
- SLC4A8 | c.2327G>T p.G776V | Missense Mutation (SNP) | VAF 27/106 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60653799; called by muse, mutect2, varscan2
- THADA | c.4126A>G p.I1376V | Missense Mutation (SNP) | VAF 32/110 reads (29%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV57685635; called by muse, mutect2, varscan2
- TMEM45A | c.589-1G>C p.X197_splice | Splice Site (SNP) | VAF 14/60 reads (23%) | catalogued as COSV60253937; called by muse, varscan2
- TRPC4 | c.2392G>C p.D798H (on ENST00000379705 / NM_016179.4; = p.D803H on NM_003306.3) | Missense Mutation (SNP) | VAF 22/75 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.781); catalogued as COSV59003042, COSV59009226; called by muse, mutect2, varscan2
- TXNIP | c.1156C>T p.L386F | Missense Mutation (SNP) | VAF 14/42 reads (33%) | SIFT tolerated, low confidence (0.62); PolyPhen benign (0.003); catalogued as COSV65220666; called by muse, mutect2
- DOCK11 | c.4546A>G p.T1516A | Missense Mutation (SNP) | VAF 4/86 reads (5%) | SIFT deleterious (0); PolyPhen possibly damaging (0.643); called by muse, mutect2
- PDS5B | c.204del p.L69Sfs*12 | Frame Shift Del (DEL) | VAF 29/114 reads (25%) | called by mutect2, pindel, varscan2
- GNB1 | c.531G>A p.T177= | Silent (SNP) | VAF 12/50 reads (24%) | catalogued as rs755635323, COSV66100764; called by muse, mutect2, varscan2
- LRRC55 | c.498C>T p.D166= | Silent (SNP) | VAF 27/87 reads (31%) | catalogued as rs1189948851, COSV73006621; called by muse, mutect2, varscan2
- LRTM2 | c.855G>A p.P285= | Silent (SNP) | VAF 26/79 reads (33%) | catalogued as rs754181370, COSV54563541; called by muse, mutect2, varscan2
- RELN | c.876G>A p.A292= | Silent (SNP) | VAF 13/77 reads (17%) | catalogued as rs757968034, COSV59008270; called by muse, mutect2, varscan2
- SLC22A7 | c.459C>T p.A153= (on ENST00000372585 / NM_153320.2; = p.A151= on NM_006672.3) | Silent (SNP) | VAF 31/94 reads (33%) | catalogued as rs1397941830, COSV65353694; called by muse, mutect2, varscan2
- SLC4A10 | c.2202T>C p.F734= (on ENST00000446997 / NM_001354461.2; = p.F704= on NM_022058.4 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 32/126 reads (25%) | catalogued as COSV55783048; called by muse, mutect2, varscan2
- SYNE1 | c.15144C>T p.N5048= (on ENST00000367255 / NM_182961.4; = p.N4977= on NM_033071.3) | Silent (SNP) | VAF 20/64 reads (31%) | catalogued as rs1391706329, COSV55005862; called by muse, mutect2, varscan2
- TXNIP | c.1158C>T p.L386= | Silent (SNP) | VAF 14/41 reads (34%) | catalogued as COSV65220675; called by muse, mutect2
- USP30 | c.1470G>T p.L490= | Silent (SNP) | VAF 5/41 reads (12%) | catalogued as COSV57449616; called by muse, mutect2, varscan2
